Gene-level copy-number profile of tumor specimen HTMCP-03-06-02197-01A from CGCI case HTMCP-03-06-02197, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 48.6 years (17,739 days).
Specimen HTMCP-03-06-02197-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc1555e0-7729-4c22-820f-6cce46d583d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02197-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/b74644a9-91fb-4f3d-a6fb-f6851542ec29

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 12,366; copy number 2: 40,121; copy number 3: 4,982; copy number 4: 894; copy number 5: 5; copy number 7: 27.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,157,443, 3 genes: OR7E103P, UNC93B4, OR7E99P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,631,389–189,897,276, 1 gene, copy number 5 (within-gene range 3–5): TP63.
- chr3:189,829,922–190,145,107, 4 genes, copy number 5 (within-gene range 3–5): MIR944, P3H2, MTAPP2, P3H2-AS1.
- chr11:100,641,975–102,378,670, 27 genes, copy number 7: RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2.

Autosomal genes at a single copy (total copy number 1): 12,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
